Surgical pathology report (de-identified scan), TCGA case TCGA-14-1034, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1034-02B (Recurrent Tumor).

[page 1 of 2]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

* Final Report *

Document Type:

Document Date:

Document Status:

Document Title: Anatomic Pathology Report

Encounter info:

* Final Report *

Anatomic Pathology Report

Patient: [REDACTED]
Age: [REDACTED] Sex: F DOB: [REDACTED]
Patient Number: [REDACTED]
Financial Number: [REDACTED]
Room/Bed: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

Accession Number: [REDACTED]

Date Collected:

Date Received:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT PARIETAL, RESECTION, FS1A: GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT PARIETAL, RESECTION: GLIOBLASTOMA MULTIFORME.

Verified:

(Electronic Signature)

1CD-0-3
glioblastoma multiforme 9440/3
Site: Brain, (L) parietal C71.3

lu
2/17/15

SPECIMEN:

1. Left parietal brain lesion.
2. Left parietal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

year-old white female with recurrent brain lesion - GBM.

NAME OF OPERATION: Left parietal crani for tumor.

PREOPERATIVE DIAGNOSIS: Recurrent GBM.

Printed by:

Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

AP Report

* Final Report *

GROSS DESCRIPTION:

The specimen is received in two parts, each labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation, labeled "left parietal brain lesion." The specimen consists of a small piece of grey, soft tissue. A portion of the tissue is frozen for intraoperative consultation and the remnant of the cryoblock is submitted in cassette "FS1A." The remainder of the tissue is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "left parietal brain lesion." The specimen consists of multiple pieces of grey-tan tissue, measuring 3.2 x 2.5 x 2.5 cm in aggregate. Representative sections are submitted in cassettes "2A" through "2C."

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT PARIETAL BRAIN LESION (FROZEN SECTION): GLIOBLASTOMA MULTIFORME.

Pathologist:

TISSUE COMMITTEE CODE:

Resident:

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.9

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Source: NCI Genomic Data Commons file 56e5a5bd-f719-4aed-96c7-a67297af6f60 (TCGA-14-1034.490E1C09-0B6A-469D-8DB8-846EB33FFCB8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).